Somatic mutation profile of tumor specimen TCGA-D8-A1X9-01A (aliquot TCGA-D8-A1X9-01A-12D-A159-09) from TCGA case TCGA-D8-A1X9, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.9 years (24,417 days).
Specimen TCGA-D8-A1X9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8dc5f813-68fa-464c-a047-c0815bf64132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1X9-10A (Blood Derived Normal), aliquot TCGA-D8-A1X9-10A-01D-A17G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ade4ebed-61a4-4071-8be5-c6c56e614c86

The open-access MAF lists 93 somatic variants for this specimen: 76 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 15, Nonsense Mutation 6, Splice Site 3, Frame Shift Del 3, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | hotspot (GDC flag); catalogued as COSV61685158, COSV61687482, COSV61687686; called by muse, mutect2, varscan2
- AC004593.2 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV56102873; called by muse, mutect2, varscan2
- AHNAK2 | c.8803C>T p.P2935S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs761922907, COSV60933224; called by muse, mutect2, varscan2
- ANXA6 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV62908686; called by muse, mutect2, varscan2
- ATL3 | c.422T>A p.M141K | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60298549; called by muse, mutect2, varscan2
- BCKDK | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV54894274; called by muse, mutect2, varscan2
- BTK | c.178A>G p.K60E | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV58124230; called by muse, mutect2, varscan2
- CCDC39 | c.2395G>T p.V799L | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as COSV56495014; called by muse, mutect2, varscan2
- CCT3 | c.773T>G p.I258S | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55291919; called by muse, mutect2, varscan2
- CDH10 | c.154C>A p.Q52K | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV100050230; called by muse, mutect2, varscan2
- CEP152 | c.2218A>T p.K740* | Nonsense Mutation (SNP) | VAF 16/45 reads (36%) | catalogued as COSV57865720; called by muse, mutect2, varscan2
- CEP152 | c.2217G>T p.E739D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV57865741; called by muse, mutect2, varscan2
- COMP | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV55876741; called by muse, mutect2, varscan2
- COQ3 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as COSV54642433; called by muse, mutect2, varscan2
- CTU2 | c.143G>T p.R48M | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56384407; called by muse, mutect2, varscan2
- DALRD3 | c.910A>C p.K304Q (on ENST00000341949 / NM_001009996.3; = p.K137Q on NM_018114.5) | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100482752; called by muse, mutect2
- DENND4B | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57846015; called by muse, mutect2, varscan2
- DGCR8 | c.563T>G p.L188R | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.037); catalogued as COSV61228979; called by muse, mutect2, varscan2
- DMRTC2 | c.1073G>T p.G358V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54188788; called by muse, mutect2, varscan2
- EIF4A3 | c.473A>T p.H158L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV53922296; called by muse, mutect2, varscan2
- F8 | c.5404T>G p.Y1802D | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64279447; called by muse, mutect2, varscan2
- FAM13B | c.1521G>C p.M507I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV50376322; called by muse, mutect2, varscan2
- FOXP1 | c.1348+1G>T p.X450_splice | Splice Site (SNP) | VAF 27/65 reads (42%) | catalogued as COSV59556331; called by muse, mutect2, varscan2
- FSD2 | c.923C>A p.T308K | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.435); catalogued as COSV100575306, COSV58013539; called by muse, mutect2, varscan2
- GLI3 | c.986C>A p.S329* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as COSV67895652; called by muse, mutect2
- GRIN2C | c.2239A>C p.T747P | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV99500611; called by muse, mutect2, varscan2
- HACE1 | c.1777-1G>T p.X593_splice | Splice Site (SNP) | VAF 15/20 reads (75%) | catalogued as COSV53508723; called by muse, mutect2, varscan2
- HIBADH | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55317589; called by muse, mutect2, varscan2
- ITIH1 | c.1916C>A p.P639H | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV56259084; called by muse, mutect2, varscan2
- KIDINS220 | c.3796T>C p.W1266R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56760122; called by muse, mutect2, varscan2
- KIF19 | c.159C>A p.D53E | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV63430774; called by muse, mutect2, varscan2
- LCT | c.984A>T p.K328N | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV51549638, COSV51558643; called by muse, mutect2, varscan2
- LRRC37B | c.1351C>T p.L451F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.166); catalogued as COSV58955445; called by muse, mutect2, varscan2
- MAP1LC3B2 | c.333G>T p.M111I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs1416499719, COSV61010734; called by muse, mutect2, varscan2
- MLH1 | c.2126C>A p.P709Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51625267; called by muse, mutect2, varscan2
- MYRIP | c.388A>C p.K130Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV56884071; called by muse, mutect2, varscan2
- NDUFAF6 | c.644C>T p.T215I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV99712618; called by muse, mutect2
- NDUFAF6 | c.646T>G p.C216G | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV99712619; called by muse, mutect2
- NHS | c.1355C>A p.A452E | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV66284019; called by muse, mutect2, varscan2
- NOBOX | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV56198352; called by muse, mutect2
- NRCAM | c.1464G>A p.W488* (on ENST00000379028 / NM_001371124.1; = p.W482* on NM_005010.4 and 21 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV104418239, COSV61035332; called by muse, mutect2, varscan2
- OGDH | c.1692G>C p.K564N | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV56058091, COSV99759754; called by muse, mutect2, varscan2
- OR13J1 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.943); catalogued as COSV65070428; called by muse, mutect2, varscan2
- OR52B2 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV73209708; called by muse, mutect2, varscan2
- OR7C1 | c.845C>A p.T282N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV50184682; called by muse, mutect2, varscan2
- P4HA1 | c.1508G>T p.C503F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54965713; called by muse, mutect2, varscan2
- PAGE1 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV65998942; called by muse, mutect2, varscan2
- PDPR | c.475C>G p.P159A | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV55357481, COSV99847975; called by muse, mutect2, varscan2
- PGM5 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs141668530; called by muse, mutect2, varscan2
- PHOSPHO2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs753729243, COSV55868928, COSV55870160; called by muse, mutect2, varscan2
- PITPNC1 | c.217A>T p.R73* | Nonsense Mutation (SNP) | VAF 26/56 reads (46%) | catalogued as COSV55459387; called by muse, mutect2, varscan2
- PITRM1 | c.2893G>A p.A965T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs534536142, COSV56541014; called by muse, mutect2, varscan2
- RERE | c.2006C>G p.T669R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.247); catalogued as COSV61952292; called by muse, mutect2, varscan2
- RIN3 | c.1629G>T p.M543I | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.006); catalogued as COSV53656890; called by muse, mutect2, varscan2
- RYR1 | c.12200T>A p.L4067H | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62112855; called by muse, mutect2, varscan2
- SDCCAG8 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV59419021; called by muse, mutect2, varscan2
- SEMA3D | c.2152C>A p.Q718K | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs1353399461, COSV52406623; called by muse, mutect2, varscan2
- SLC38A10 | c.2606G>A p.G869D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs768460185, COSV55849882; called by muse, mutect2
- SOX6 | c.2023G>A p.A675T (on ENST00000528429 / NM_001145819.2; = p.A648T on NM_017508.3) | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57059714; called by muse, mutect2, varscan2
- SPTA1 | c.1645G>T p.D549Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV63758592, COSV63760820; called by muse, mutect2, varscan2
- TBC1D16 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs993990631; called by muse, mutect2
- TECPR2 | c.100del p.I34Sfs*34 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as COSV63974752; called by mutect2, pindel, varscan2
- TFDP2 | c.889G>C p.E297Q (on ENST00000489671 / NM_001178139.2; = p.E237Q on NM_006286.5) | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57712216; called by muse, mutect2, varscan2
- TKT | c.545T>A p.L182Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56247321; called by muse, mutect2, varscan2
- TRAPPC8 | c.885T>G p.F295L | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV51978287; called by muse, mutect2, varscan2
- TSHZ2 | c.896A>T p.H299L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61592095; called by muse, mutect2, varscan2
- TUBE1 | c.931G>T p.D311Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64088188; called by muse, mutect2, varscan2
- UGT2B4 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 19/52 reads (37%) | catalogued as COSV59321232; called by muse, mutect2, varscan2
- WWC3 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs925631479, COSV66506647, COSV66508449; called by muse, mutect2, varscan2
- ZNF408 | c.911A>T p.Y304F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs932534447, COSV61239535; called by muse, mutect2, varscan2
- IFNA6 | c.257_267del p.Q86Pfs*13 | Frame Shift Del (DEL) | VAF 17/34 reads (50%) | called by mutect2, pindel, varscan2
- IGKV6-21 | c.85T>G p.F29V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- MEGF8 | c.6024del p.K2009Sfs*34 (on ENST00000251268 / NM_001271938.2; = p.K1942Sfs*34 on NM_001410.3) | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- PTPA | c.790+2_790+13del p.X264_splice (on ENST00000337738 / NM_178001.2; = p.X229_splice on NM_021131.5) | Splice Site (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- SOCS7 | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, mutect2
- VSTM4 | c.141_149del p.H47_S49del | In Frame Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- APH1A | c.180C>A p.T60= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV52530896; called by muse, mutect2, varscan2
- CHRM3 | c.1527C>A p.I509= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV55107458; called by muse, mutect2, varscan2
- CNGA3 | c.1956C>T p.N652= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as rs749868323, COSV55623097; called by muse, mutect2, varscan2
- COL1A2 | c.3675C>T p.H1225= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs755678340, COSV51967377; called by muse, mutect2, varscan2
- DSPP | c.2160T>C p.N720= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as COSV56817384; called by muse, mutect2, varscan2
- ESYT3 | c.1230G>A p.L410= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV67442305; called by muse, mutect2, varscan2
- FMO1 | c.1044C>A p.G348= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV61448073; called by muse, mutect2, varscan2
- FOS | c.1089C>T p.S363= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV57840575; called by mutect2, varscan2
- MIA2 | c.2166T>A p.P722= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV54502604, COSV54502820; called by muse, mutect2, varscan2
- OR10T2 | c.421C>T p.L141= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV57783987; called by muse, mutect2, varscan2
- PKDREJ | c.1857C>A p.T619= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV53553803; called by muse, mutect2, varscan2
- SV2B | c.369G>T p.G123= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV57702837; called by muse, mutect2, varscan2
- TREML4 | c.24C>A p.T8= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV58384797; called by muse, mutect2, varscan2
- TRIM42 | c.933C>G p.T311= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV53887437; called by muse, mutect2, varscan2
- ZNF611 | c.825A>T p.A275= | Silent (SNP) | VAF 35/52 reads (67%) | catalogued as rs111665269, COSV100160054; called by muse, mutect2, varscan2
- CCDC144B | n.2009G>C | RNA (SNP) | VAF 30/42 reads (71%) | called by muse, mutect2, varscan2
- MIR1206 | n.3G>T | RNA (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
